Gene-level copy-number profile of tumor specimen HTMCP-03-06-02074-01A from CGCI case HTMCP-03-06-02074, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 63.8 years (23,305 days).
Specimen HTMCP-03-06-02074-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file acac824c-2aeb-48ae-8f28-ab780ec70635.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02074-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/5f91d2fc-90cc-4d57-be82-e0dce3d7dca5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 671; copy number 2: 26,578; copy number 3: 25,306; copy number 4: 5,065; copy number 5: 40; copy number 6: 19; copy number 7: 26; copy number 8: 4; copy number 9: 658; copy number 10: 20.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr5:177,782,197–177,803,344, 2 genes (within-gene range 0–2): AC140125.2, AC140125.1.
- chr9:95,085,208–95,086,094, 4 genes (within-gene range 0–2): MIR23B, MIR27B, MIR3074, MIR24-1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 708 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:109,915,976–109,977,767, 2 genes, copy number 7: NFYBP1, AC078918.1.
- chr5:58,198–45,895,970, 679 genes, copy number 8–10 (broad region; genes not listed).
- chr21:36,632,681–38,121,345, 27 genes, copy number 7–9 (within-gene range 1–9): AP000696.1, AP000697.1, SIM2, HLCS, HLCS-IT1, RNA5SP491, DPRXP5, AP000704.1, Y_RNA, MRPL20P1, RIPPLY3, RNU6-696P, PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1, AP001437.2, AP001437.1, DYRK1A, AP001407.1, KCNJ6, KCNJ6-AS1.

Autosomal genes at a single copy (total copy number 1): 671. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
